Somatic mutation profile of tumor specimen MP2PRT-PAUIAH-TMP1-A (aliquot MP2PRT-PAUIAH-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUIAH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,652 days).
Specimen MP2PRT-PAUIAH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40f4c838-ffb4-44c4-a651-e9f0333d3fbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIAH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIAH-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0501c4d-2f3b-4c7a-b7a8-28fd4040afef

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, In Frame Ins 1, Intron 1, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 153/382 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs899043467; called by muse, mutect2, varscan2
- KDM6A | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 198/218 reads (91%) | catalogued as COSV99060753; called by muse, mutect2, varscan2
- PALMD | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 167/421 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs749638006; called by muse, mutect2, varscan2
- TRHDE | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1211108472, COSV53847133; called by muse, mutect2
- XBP1 | c.509del p.R170Lfs*25 | Frame Shift Del (DEL) | VAF 47/248 reads (19%) | catalogued as COSV53274438; called by pindel*, varscan2
- IGLV4-60 | c.360_362del p.T120del | In Frame Del (DEL) | VAF 24/83 reads (29%) | called by pindel*, varscan2
- MUC16 | c.10734A>C p.E3578D | Missense Mutation (SNP) | VAF 171/426 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SNX27 | c.1286_1287insGGGGTC p.F429delinsLGS | In Frame Ins (INS) | VAF 84/260 reads (32%) | called by mutect2, pindel, varscan2
- URB2 | c.1985T>G p.F662C | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX5 | c.954G>T p.L318= | Silent (SNP) | VAF 133/363 reads (37%) | catalogued as COSV58637777; called by muse, mutect2, varscan2
- SPOCK1 | c.831C>T p.Y277= | Silent (SNP) | VAF 176/481 reads (37%) | catalogued as rs138803538, COSV56457823; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46465C>T | Intron (SNP) | VAF 229/638 reads (36%) | called by muse, mutect2, varscan2
